Somatic mutation profile of tumor specimen TARGET-10-PARUKW-09A (aliquot TARGET-10-PARUKW-09A-01D) from TARGET case TARGET-10-PARUKW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.8 years (3,576 days).
Specimen TARGET-10-PARUKW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe0d8f69-516f-4c26-b554-75fee03985bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARUKW-10A (Blood Derived Normal), aliquot TARGET-10-PARUKW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c22203e-7be8-4ac2-bd56-82b2df9ea3b3

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Intron 3, Frame Shift Ins 3, Silent 3, 3'UTR 1, RNA 1, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 31/86 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CFAP46 | c.1337C>T p.T446M | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1203078672; called by muse, mutect2, varscan2
- CTBP1 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52076667; called by muse, mutect2, varscan2
- EHD3 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs144717418; called by muse, mutect2, varscan2
- ETV6 | c.1166_1167insTTACTTTTTAC p.M389Ifs*20 | Frame Shift Ins (INS) | VAF 49/156 reads (31%) | catalogued as COSV56766871; called by mutect2, pindel, varscan2
- EZH2 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as CM120183, COSV57456778, COSV57463449; called by muse, mutect2, varscan2
- FRMPD3 | c.4211C>T p.S1404L | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs755437325, COSV52196755; called by muse, mutect2, varscan2
- GDAP1L1 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1424565874, COSV61158982; called by muse, mutect2, varscan2
- MAB21L1 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 95/189 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59824468; called by muse, mutect2, varscan2
- MTCL1 | c.2242G>A p.E748K (on ENST00000306329 / NM_001378206.1; = p.E388K on NM_015210.4) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs960065995, COSV60412092; called by muse, mutect2, varscan2
- NGEF | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755477382, COSV50916937, COSV99889693; called by muse, mutect2, varscan2
- NOTCH1 | c.5039T>G p.I1680S | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV53025693, COSV53032125, COSV53096766; called by muse, varscan2
- NR6A1 | c.680C>A p.P227Q (on ENST00000487099 / NM_033334.4; = p.P222Q on NM_001489.5) | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV60638133; called by muse, mutect2, varscan2
- PCDHA6 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); catalogued as rs782489134, COSV65352609; called by muse, mutect2, varscan2
- RANBP2 | c.3776G>A p.G1259E | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV51709146; called by muse, mutect2, varscan2
- RUNX1T1 | c.728G>A p.R243Q (on ENST00000265814 / NM_001198628.1; = p.R216Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs779166132, COSV56138575, COSV56148911, COSV56149532; called by muse, mutect2, varscan2
- STMN2 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs1320736929, COSV55222725; called by muse, mutect2, varscan2
- SVIL | c.4751C>T p.P1584L (on ENST00000355867 / NM_021738.3; = p.P1158L on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs760195587, COSV63448465; called by muse, mutect2, varscan2
- VWF | c.4024C>T p.R1342C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs61749404, CM070341; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASXL2 | c.2604_2605insCGTCCCT p.S869Rfs*11 | Frame Shift Ins (INS) | VAF 46/123 reads (37%) | called by mutect2, pindel, varscan2
- COL5A2 | c.2330G>T p.G777V | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT2C | c.9905_9906insTGTC p.T3303Vfs*24 | Frame Shift Ins (INS) | VAF 7/63 reads (11%) | called by mutect2, pindel
- SLC1A5 | c.1025_1026insCCTCATGAC p.T342_P343insLMT | In Frame Ins (INS) | VAF 22/47 reads (47%) | called by mutect2, pindel, varscan2
- HERC2 | c.8820C>T p.S2940= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs140556070; called by muse, mutect2, varscan2
- HOATZ | c.261G>A p.A87= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs775579194; called by muse, mutect2
- VWDE | c.849C>T p.I283= | Silent (SNP) | VAF 56/112 reads (50%) | catalogued as rs1335708351, COSV51721763; called by muse, mutect2, varscan2
- AC136759.1 | n.583G>A | RNA (SNP) | VAF 14/224 reads (6%) | catalogued as rs755169455; called by muse, mutect2
- COX7A2 | c.*74G>A | 3'UTR (SNP) | VAF 10/206 reads (5%) | catalogued as rs1430992156; called by muse, mutect2
- LAT | chr16:28984901 G>A | 5'Flank (SNP) | VAF 22/43 reads (51%) | catalogued as rs549994584, COSV57956857; called by muse, varscan2
- NLGN3 | c.518-15G>A | Intron (SNP) | VAF 78/160 reads (49%) | catalogued as rs771781705; called by muse, mutect2, varscan2
- OSCP1 | c.849+90G>T | Intron (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- WIPI2 | c.740+119C>T | Intron (SNP) | VAF 9/68 reads (13%) | catalogued as rs532900093; called by muse, mutect2, varscan2
